Somatic mutation profile of tumor specimen TARGET-30-PAPZFW-01A (aliquot TARGET-30-PAPZFW-01A-01D) from TARGET case TARGET-30-PAPZFW, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 3.7 years (1,342 days).
Specimen TARGET-30-PAPZFW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec955e10-0bbd-4922-8f86-e5aa13ed1bed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPZFW-10A (Blood Derived Normal), aliquot TARGET-30-PAPZFW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ed2f9a7-9c82-4ec6-80e6-829239277699

The open-access MAF lists 40 somatic variants for this specimen: 28 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Frame Shift Del 1, Splice Site 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.8048G>T p.R2683I | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67977855; called by muse, mutect2, varscan2
- C1QTNF8 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as rs144257076; called by muse, varscan2
- CRMP1 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61478075; called by muse, mutect2, varscan2
- DPYSL3 | c.374A>T p.E125V | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV58323696; called by muse, mutect2, varscan2
- ENPP7 | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs374131130, COSV60385184; called by muse, mutect2, varscan2
- GLI1 | c.940C>G p.R314G | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57357532, COSV57359048, COSV57364183; called by muse, mutect2, varscan2
- HELZ2 | c.2322C>A p.H774Q (on ENST00000467148 / NM_001037335.2; = p.H205Q on NM_033405.3) | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64408952; called by muse, mutect2, varscan2
- KCNJ4 | c.885G>T p.E295D | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57856019; called by muse, mutect2, varscan2
- KCNK6 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV54578746; called by muse, mutect2, varscan2
- LCMT2 | c.1459G>T p.V487L | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV59789403; called by muse, mutect2, varscan2
- LECT2 | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV50846695; called by muse, mutect2, varscan2
- MUC16 | c.15257G>A p.R5086H | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.193); catalogued as rs533387298, COSV67442388, COSV67493775; called by muse, mutect2, varscan2
- MYH2 | c.101C>A p.A34D | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV55430984; called by muse, mutect2, varscan2
- NPC1 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1406484313, COSV52576062; called by muse, mutect2, varscan2
- NR1H3 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV68008072; called by muse, mutect2, varscan2
- OAS3 | c.714G>C p.E238D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745714139, COSV57443843; called by muse, mutect2, varscan2
- OR8D2 | c.418G>C p.V140L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV62487991, COSV62488659; called by muse, mutect2, varscan2
- PCDHA6 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 25/270 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100971530, COSV65348503; called by muse, mutect2
- PIK3C2G | c.1979C>T p.S660F (on ENST00000676171; = p.S619F on NM_004570.5) | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs767852668, COSV56795879; called by muse, mutect2, varscan2
- PLCE1 | c.3062A>G p.Q1021R | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV53335636; called by muse, mutect2, varscan2
- PRIMPOL | c.1097-1G>A p.X366_splice | Splice Site (SNP) | VAF 19/47 reads (40%) | catalogued as COSV59247763; called by muse, mutect2, varscan2
- PRPF8 | c.6152G>C p.G2051A | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56772638; called by muse, mutect2, varscan2
- SLC22A18 | c.1013T>A p.L338Q | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV56538832; called by muse, mutect2, varscan2
- SNX33 | c.518C>G p.A173G | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV57912604; called by muse, mutect2, varscan2
- STAG1 | c.3700del p.A1234Lfs*3 | Frame Shift Del (DEL) | VAF 32/99 reads (32%) | catalogued as COSV52600644; called by mutect2, pindel, varscan2
- ZNF611 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1457011074, COSV60539417; called by muse, mutect2, varscan2
- LCE3C | c.155G>A p.C52Y | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NPAS4 | c.1651G>C p.E551Q | Missense Mutation (SNP) | VAF 11/272 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.11); called by muse, mutect2
- CEACAM4 | c.729C>G p.V243= | Silent (SNP) | VAF 29/149 reads (19%) | catalogued as COSV55730528; called by muse, mutect2, varscan2
- CILP2 | c.2880C>A p.G960= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV52272368; called by muse, mutect2, varscan2
- GPR156 | c.1824C>A p.A608= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV59937807; called by muse, mutect2, varscan2
- KIF26B | c.2358G>A p.A786= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as rs148065443; called by muse, mutect2
- NCAM1 | c.2052G>T p.V684= (on ENST00000316851 / NM_181351.5; = p.V674= on NM_000615.7) | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV57509868; called by muse, mutect2, varscan2
- NCOA3 | c.2517G>A p.L839= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV59065203; called by muse, mutect2, varscan2
- TG | c.1002G>A p.G334= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV55064267; called by muse, mutect2, varscan2
- TRIM16 | c.1545C>T p.T515= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as rs1400307188, COSV60885484; called by muse, mutect2, varscan2
- VCX | c.30T>C p.P10= | Silent (SNP) | VAF 28/235 reads (12%) | catalogued as COSV100406385; called by muse, mutect2, varscan2
- WDR75 | c.2226A>G p.P742= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV59104633; called by muse, mutect2, varscan2
- ZNF311 | c.1596T>C p.C532= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV65852810; called by muse, mutect2, varscan2
- ABCC9 | chr12:21801110 G>A | 3'Flank (SNP) | VAF 17/56 reads (30%) | catalogued as COSV53961927; called by muse, mutect2, varscan2
